Surgical pathology report (de-identified scan), TCGA case TCGA-23-1113, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1113-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGY REPORT

PATIENT: [REDACTED]

PATH #: [REDACTED]

Hospital No.: [REDACTED]

A/S: [REDACTED]

Date of Birth: [REDACTED]

Soc. Sec. No: [REDACTED]

Location: [REDACTED]

Pathologist: [REDACTED]

Assistant: [REDACTED]

Attending MD: [REDACTED]

Ordering MD: [REDACTED]

Copies To: [REDACTED]

=====

DIAGNOSIS:

- 1-4. PELVIC NODULE, PELVIC PERITONEUM, UMBILICAL HERNIA, BLADDER PERITONEUM, BIOPSIES:
-Positive for high-grade papillary serous carcinoma
- 5-9. UTERUS, CERVIX, RIGHT AND LEFT OVARIES AND FALLOPIAN TUBES, HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
-Papillary serous carcinoma, high-grade
-Tumor involves both right and left ovaries, replacing most of the ovarian parenchyma
-Tumor also involves the right and left fallopian tubes mucosa with transmural invasion
-Benign endometrial polyp in a background of secretory endometrium
-The myometrium is unremarkable
-The uterine serosa is unremarkable
-Cervix shows metastatic deposits of papillary serous carcinoma in the lymphatic spaces and submucosal stroma
10. APPENDIX, RESECTION:
-Metastatic high-grade papillary serous carcinoma involving periappendiceal soft tissue
- 11-17. SIGMOID IMPLANT, TUMOR NODULE, URETERAL SACRAL NODULE, OMENTUM, LESSER SAC, COLON NODULE, BLADDER NODULE, BIOPSIES:
-Positive for high-grade papillary serous carcinoma

=====

HISTORY: Ovarian carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1. PELVIC NODULE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two firm pink-white portions of tissue measuring 2.8 and 3.0 cm in greatest dimensions. The cut surfaces display homogeneous, friable, tan-white tumor with hemorrhage. Representative section.

A: 1

[page 2 of 4]
2. PELVIC PERITONEUM

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a soft yellow-tan 5.2 x 3.1 x 0.4 cm irregular portion of membranous tissue. The specimen is studded with firm, white tumor nodules. Representative section.

B: 1

3. UMBILICAL HERNIA

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a portion of saccular fibroadipose and fibromembranous tissue, 4.9 x 3.2 x 0.9 cm in greatest dimensions. On sectioning a cystic area containing hemorrhage is identified. Representative section.

C: 1

4. BLADDER PERITONEUM

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are two firm pink-white portions of tissue measuring 1.3 and 2.2 cm in greatest dimensions. Representative sections.

D: 2

5. LEFT TUBE AND OVARY

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a fallopian tube measuring 3.6 cm in length, and 0.7 cm in average diameter. The tube is diffusely indurated. The fimbriated end is indurated with firm, white tumor. On sectioning the lumen measures 0.3 cm in diameter. Attached to the fallopian tube is a 3.9 x 3.6 x 2.8 cm solid and cystic ovary which on sectioning is completely replaced by firm, white tumor. Representative sections.

E: fallopian tube-2

F-H: ovary-1 each

6. RIGHT TUBE AND OVARY

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in the fresh state in the Operating Room for frozen section diagnosis and subsequently fixed in formalin is a fallopian tube measuring 4.3 cm in length, and 1.2 cm. in average diameter. The tube is diffusely indurated and distended by firm white tumor. The fimbriated end is identified grossly. On sectioning the lumen measures 0.4 cm in diameter. Attached to the segment of fallopian tube is a 4.3 x 3.4 x 3.2 cm cystic and solid ovary which on sectioning is completely replaced by firm, white tumor. Representative sections.

I: frozen-section control#1-2

J: fallopian tube-2

K-M: ovary-1 each

7. UTERUS

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in the fresh state in the Operating Room for intra-operative gross consultation and subsequently fixed in formalin is a uterus without attached adnexa which weighs 270 grams. The uterine corpus is enlarged, measuring 6.3 cm superior to inferior, 8.4 cm cornu to cornu, and 7.1 cm anterior to posterior. The serosa is tan red with focal hemorrhage. The cervix has a length of 4.3 cm and a diameter of 4.1 cm. There is a 1.5 cm slit-like patent os. The ectocervical mucosa is tan-pink and smooth without obvious lesions. The transformation zone is distinct. The endocervical canal is 3.1 cm in length and is tan and rugose. The endometrial cavity is 5.2 cm in length, 3.7 cm in width, and is lined by a soft tan, smooth endometrium with a thickness of 0.2 cm. The endometrium contains two tan-brown soft polyps measuring 1.0 and 2.4 cm in greatest dimensions. The myometrium is 2.3 cm in maximum thickness. The

[page 3 of 4]
myometrium is grossly unremarkable. Representative sections.

N: anterior uterine corpus-1
O: anterior uterine corpus polyp-2
P: anterior cervix-1
Q: posterior uterine corpus-1
R: posterior uterine corpus polyp-1
S: posterior cervix-1

8. LEFT OVARY TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a firm white 2.3 x 1.8 x 1.4 cm irregular portion of tissue. Representative section.

T: 1

9. RIGHT OVARY TUMOR

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a firm white 2.8 x 1.7 x 1.6 cm irregular portion of tissue. Representative section.

U: 1

10. APPENDIX

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a vermiform appendix, 5.7 cm long and 0.8 cm in maximum diameter, with attached fat up to 0.9 cm in width and 1.1 cm in thickness. The external surface is tan-pink and bosselated with firm white tumor nodules. No exudate is seen. The wall varies in thickness up to 0.2 cm and is firm and tan-white. There is no gross perforation. The lumen measures up to 0.3 cm and contains a small amount of hemorrhagic material. No fecolith is identified. Representative sections.

V: 3

11. SIGMOID IMPLANT

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are five firm white portions of tissue measuring from 0.6 to 0.9 cm in greatest dimension. Representative sections.

W: 3

12. TUMOR NODULE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are six soft white portions of tissue measuring from 0.5 to 1.0 cm in greatest dimension. Representative sections.

X: 3

13. URETERAL SACRAL NODULE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a firm pink-white 2.8 x 1.6 x 1.4 cm irregular portion of tissue. Representative section.

Y: 1

14. OMENTUM

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a 22.5 x 5.8 x 3.4 cm aggregate of indurated adipose tissue with diffuse, firm, white tumor nodularity. Representative section.

Z: 1

15. LESSER SAC

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a firm yellow-white 2.3 x 1.4 x 0.8 cm irregular portion of tissue. Representative section.

[page 4 of 4]
A2: 1

16. COLON NODULE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin are six firm pink-white portions of tissue measuring from 0.6 to 1.2 cm in greatest dimension. Representative sections.

B2: 2

17. BLADDER NODULE

Labeled with the patient's name, labeled as designated on the specimen requisition form, and received in formalin is a firm pink-white 1.3 x 0.5 x 0.2 cm irregular portion of tissue. Entirely submitted.

C2: 1

OPERATIVE CONSULT (FROZEN):

#6. MALIGNANT TUMOR, FAVOR PAPILLARY SEROUS CARCINOMA

Referred to permanent

OPERATIVE CONSULT (GROSS):

#7. UTERUS WITH ENDOMETRIAL POLYPS:

Source: NCI Genomic Data Commons file 0f6bf0d7-18f5-47f4-854f-f918c4a688c8 (TCGA-23-1113.A7FA848E-2492-4802-9CB2-58EC66FC3DD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).